Somatic mutation profile of tumor specimen TARGET-30-PAPRMJ-01A (aliquot TARGET-30-PAPRMJ-01A-01D) from TARGET case TARGET-30-PAPRMJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 3.7 years (1,339 days).
Specimen TARGET-30-PAPRMJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb5d8ee8-0590-4173-a4d4-01284ded1866.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPRMJ-10A (Blood Derived Normal), aliquot TARGET-30-PAPRMJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da9993b6-ed4d-451e-8edb-1f0d16196d3b

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7333C>A p.L2445I | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV71284071; called by muse, mutect2, varscan2
- GDF5 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1480820638, COSV65499677; called by muse, mutect2
- LILRA1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.909); catalogued as rs376588218; called by muse, varscan2
- MRPS6 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 33/492 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as COSV62971431; called by muse, mutect2
- PHYHIP | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751865156, COSV58688118; called by muse, mutect2, varscan2
- PRR19 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV56623906; called by muse, mutect2, varscan2
- PZP | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54355439, COSV54363756; called by muse, mutect2, varscan2
- SPTA1 | c.3470T>C p.I1157T | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV63749666; called by muse, mutect2, varscan2
- TCHH | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 42/219 reads (19%) | PolyPhen possibly damaging (0.725); catalogued as COSV64273274; called by muse, mutect2, varscan2
- USP43 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772015786, COSV53300170; called by muse, mutect2, varscan2
- P3H3 | c.1108C>A p.L370I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.292); called by muse, mutect2
- TROAP | c.529_544delinsT p.T177_R181del | In Frame Del (DEL) | VAF 5/33 reads (15%) | called by pindel, varscan2*
- SKA2 | c.336G>A p.E112= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV57520810; called by muse, mutect2, varscan2
- ZFHX3 | c.2097C>G p.G699= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV51710358; called by muse, mutect2, varscan2
- ZNF460 | c.252C>G p.V84= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV64415354; called by muse, mutect2, varscan2
